Somatic mutation profile of tumor specimen MP2PRT-PATUUD-TBP1-B (aliquot MP2PRT-PATUUD-TBP1-B-1-0-D-A835-36) from MP2PRT case MP2PRT-PATUUD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.1 years (4,435 days).
Specimen MP2PRT-PATUUD-TBP1-B: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c56087e-9cb3-429d-b58e-23109bb6538b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATUUD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATUUD-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d8b46e9-59e4-44a9-a2f1-a4d4bfe8b054

The open-access MAF lists 26 somatic variants for this specimen: 25 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 21, Nonsense Mutation 2, Splice Region 1, Silent 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6112C>T p.R2038W | Missense Mutation (SNP) | VAF 60/431 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs61750643, CM970019; ClinVar: not provided / pathogenic; called by muse, mutect2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/506 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ARL14 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 77/364 reads (21%) | catalogued as rs180925087; called by muse, varscan2
- ETV6 | c.1036T>C p.Y346H | Missense Mutation (SNP) | VAF 94/474 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1230474319; called by muse, mutect2, varscan2
- FLT1 | c.3471G>T p.L1157F | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs573870646; called by muse, mutect2, varscan2
- GNL3L | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 205/1130 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs372448751; called by muse, varscan2
- HCN1 | c.2462C>T p.A821V | Missense Mutation (SNP) | VAF 154/876 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs371602396; called by muse, varscan2
- HK3 | c.2188C>T p.R730C | Missense Mutation (SNP) | VAF 47/988 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs780234736, COSV52837541; called by muse, mutect2
- LRP2 | c.5072C>T p.A1691V | Missense Mutation (SNP) | VAF 50/258 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0.017); catalogued as rs145365776, COSV104378305; called by muse, mutect2, varscan2
- NID1 | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 181/497 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs148420954; called by muse, varscan2
- PCDHAC2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 30/1036 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53848370; called by muse, mutect2
- PIM2 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 115/683 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV50236067; called by muse, mutect2, varscan2
- PLEKHG5 | c.1395C>T p.F465= (on ENST00000400915 / NM_001042663.3; = p.F428= on NM_020631.6) | Splice Region (SNP) | VAF 84/404 reads (21%) | catalogued as rs1222344225; called by muse, varscan2
- RGS3 | c.3059G>A p.R1020Q (on ENST00000350696 / NM_001282923.2; = p.R739Q on NM_130795.4) | Missense Mutation (SNP) | VAF 126/489 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1426509509, COSV100636856, COSV59512769; called by muse, mutect2, varscan2
- SPAST | c.1205C>G p.T402S | Missense Mutation (SNP) | VAF 8/248 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV99043705; called by muse, mutect2
- SPINK5 | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.273); catalogued as rs780631964, COSV56264284; called by muse, mutect2, varscan2
- TRPC7 | c.1963G>A p.V655I | Missense Mutation (SNP) | VAF 172/497 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs150500079; called by muse, mutect2, varscan2
- AKR1C2 | c.714C>A p.D238E | Missense Mutation (SNP) | VAF 54/449 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.29); called by muse, mutect2, varscan2
- ETV6 | c.141_142insGGGCCCCG p.I48Gfs*22 | Frame Shift Ins (INS) | VAF 98/692 reads (14%) | called by mutect2, pindel, varscan2
- LAMB2 | c.1757T>C p.V586A | Missense Mutation (SNP) | VAF 106/542 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH6 | c.4180A>T p.K1394* | Nonsense Mutation (SNP) | VAF 52/334 reads (16%) | called by muse, varscan2
- PIP5K1A | c.413G>A p.R138H (on ENST00000368888 / NM_001135638.2; = p.R125H on NM_003557.3) | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- SPO11 | c.1153T>C p.Y385H | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STARD13 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 99/397 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TH | c.682C>A p.Q228K (on ENST00000381178 / NM_199292.3; = p.Q197K on NM_000360.4) | Missense Mutation (SNP) | VAF 149/747 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2T4 | c.516G>C p.V172= | Silent (SNP) | VAF 30/808 reads (4%) | catalogued as rs756713706, COSV63545433; called by muse, mutect2
